TCGA case TCGA-VQ-A8PY — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ac359b60-1977-4aa9-99d3-8d17d7d66e11

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: Brazil; Age at index: 47 years; Vital status: Dead; Days to death: 436 days (1.2 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Tubular adenocarcinoma: ICD-O-3 morphology code: 8211/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 47.2 years (17,230 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 12; Lymph nodes tested: 43.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 54 days; Days to treatment end: 192 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 159 days; Days to treatment end: 201 days; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.

Follow-up (1 entry)
- Days to follow up: 436 days (1.2 years); Disease response: Tumor Free.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VQ-A8PY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 60 mg.
  Slide TCGA-VQ-A8PY-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VQ-A8PY-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VQ-A8PY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Tubular Type; Cause of death: Stomach Cancer; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Anatomic organ subdivision: Antrum/Distal; Lymph nodes examined: Yes; Tumor sample procurement country: Sao Paulo; Cancer procurement city: Barretos; History reflux disease indicator: No; Antireflux treatment: No; History barretts esophageal indicator: No; History hpylori infection indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on analyte TCGA-VQ-A8PY-01A-11R: The RNA associated with UUID 44C0AC01-F951-49B8-A399-8D993B0A59E5 was involved in an extraction error that resulted in a genotype mismatch with its corresponding tumor DNA. This only affected the tumor RNA as DNA from the tumor and normal sample have the correct matching genotype.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-VQ-A8PY-01A-11R-A414-31: The RNA associated with UUID E51E938F-91C3-426E-BF55-F680B63B0144 was involved in an extraction error that resulted in a genotype mismatch with its corresponding tumor DNA. This only affected the tumor RNA as DNA from the tumor and normal sample have the correct matching genotype.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-VQ-A8PY-01A-11R-A415-13: The RNA associated with UUID 0A0BFC7C-FD21-4211-A4A0-72A200A1C35E was involved in an extraction error that resulted in a genotype mismatch with its corresponding tumor DNA. This only affected the tumor RNA as DNA from the tumor and normal sample have the correct matching genotype.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 436 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 436 days; disease-free interval: no event (censored), 436 days; progression-free interval: no event (censored), 436 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VQ-A8PY-01A-11D-A40Z-01): tumor purity 0.32, ploidy 3.34, whole-genome doublings 1.
